Somatic mutation profile of tumor specimen TCGA-55-6968-01A (aliquot TCGA-55-6968-01A-11D-1945-08) from TCGA case TCGA-55-6968, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-55-6968-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ccfb07e-ba1b-49c3-81a7-cfcd220afcb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6968-11A (Solid Tissue Normal), aliquot TCGA-55-6968-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca1dcdf4-abd7-4052-9a7e-17f6cf09bff9

The open-access MAF lists 539 somatic variants for this specimen: 395 protein-altering or splice-affecting, 123 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 345, Silent 123, Nonsense Mutation 31, Intron 12, Frame Shift Del 10, Splice Site 6, RNA 4, 3'Flank 3, 3'UTR 1, Splice Region 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs587783921, COSV56940971; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1194037106, COSV62321000; called by muse, mutect2, varscan2
- ABCC4 | c.1964C>G p.S655* | Nonsense Mutation (SNP) | VAF 8/146 reads (5%) | catalogued as COSV65309225; called by muse, mutect2
- ABCC9 | c.2395T>A p.F799I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.53); catalogued as COSV53961478; called by muse, mutect2, varscan2
- ABHD12B | c.613A>T p.R205* (on ENST00000337334 / NM_001206673.2; = p.R128* on NM_181533.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/203 reads (22%) | catalogued as COSV61568551; called by muse, mutect2, varscan2
- ABRA | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as rs767056599, COSV61731829; called by muse, mutect2, varscan2
- ACSL6 | c.1300G>A p.G434R (on ENST00000379240; = p.G459R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99733192; called by muse, mutect2, varscan2
- ACTN4 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.027); catalogued as COSV53142611; called by muse, mutect2, varscan2
- ADAM19 | c.1935C>A p.N645K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57422066; called by muse, mutect2, varscan2
- ADAM23 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.218); catalogued as COSV52206634; called by muse, mutect2, varscan2
- ADAR | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV52711740; called by muse, mutect2, varscan2
- ADCY10 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV63238315; called by muse, mutect2, varscan2
- ADGRE1 | c.1746T>A p.N582K | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV51671448; called by muse, mutect2, varscan2
- ADGRG4 | c.4141G>A p.E1381K | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV54948418; called by muse, mutect2
- ADGRV1 | c.5768A>T p.E1923V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV67977375; called by muse, mutect2, varscan2
- AFAP1L1 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV57043631; called by muse, mutect2, varscan2
- AKAP10 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56729944; called by muse, mutect2, varscan2
- AKAP6 | c.6740C>T p.S2247L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.177); catalogued as COSV55203170; called by muse, mutect2
- AKNA | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV56310871; called by muse, mutect2, varscan2
- AKR1B15 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71150940; called by muse, mutect2, varscan2
- ALS2 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51883582; called by muse, mutect2
- ANGEL1 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as COSV51871661; called by muse, mutect2, varscan2
- ANK3 | c.4072G>A p.E1358K (on ENST00000280772 / NM_001320874.2; = p.E492K on NM_001149.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55042314; called by muse, mutect2, varscan2
- ANKRD35 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62909387, COSV62912068; called by muse, mutect2, varscan2
- AOX1 | c.3520G>C p.D1174H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs911733529, COSV99613551; called by muse, mutect2, varscan2
- ARFGEF3 | c.6378G>C p.Q2126H | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV52449187; called by muse, mutect2, varscan2
- ARHGEF11 | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59352147, COSV59354494; called by muse, mutect2, varscan2
- ARHGEF40 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV53877941; called by muse, mutect2
- ASPM | c.8295G>T p.K2765N | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV54123673, COSV54128598; called by muse, mutect2, varscan2
- ASTN2 | c.1244C>A p.T415K (on ENST00000313400 / NM_001365069.1; = p.T364K on NM_014010.5) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100529134, COSV57747172; called by muse, varscan2
- ASXL3 | c.1803G>T p.Q601H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV52455859; called by muse, mutect2, varscan2
- ATAD5 | c.3848C>T p.S1283L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1315085634, COSV58971612; called by muse, mutect2, varscan2
- ATG2A | c.2292G>C p.E764D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV65965623; called by muse, mutect2, varscan2
- ATP2A1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63919799; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV59472082; called by muse, mutect2, varscan2
- B3GNT2 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); catalogued as COSV57343740; called by muse, mutect2, varscan2
- BBS2 | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV55324895; called by muse, mutect2, varscan2
- BDP1 | c.1871C>G p.S624* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV62428545; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.866); catalogued as COSV57277982, COSV99958998; called by muse, mutect2
- C12orf71 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs1377083454, COSV70282498; called by muse, mutect2
- C2orf42 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs1286256467, COSV52448637; called by muse, mutect2
- C5 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV56323648; called by muse, mutect2, varscan2
- C7 | c.1976G>C p.C659S | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759506502, COSV57470081; called by muse, mutect2, varscan2
- C8B | c.25T>A p.W9R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV64776366; called by muse, mutect2, varscan2
- C8orf34 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as COSV61369343; called by muse, mutect2
- CABP5 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs991098570, COSV53151835; called by muse, mutect2, varscan2
- CALCRL | c.531C>A p.H177Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66473236; called by muse, mutect2, varscan2
- CATSPERG | c.1370G>C p.R457P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV53045456; called by muse, mutect2, varscan2
- CBX4 | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53964143; called by muse, mutect2
- CCDC146 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53543476; called by muse, mutect2, varscan2
- CCDC68 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61602915; called by muse, mutect2
- CCDC90B | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1242786667, COSV52623328; called by muse, mutect2
- CCNB3 | c.3450G>A p.M1150I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52069388; called by muse, mutect2, varscan2
- CCND3 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV57827644, COSV57827650; called by muse, mutect2, varscan2
- CDH12 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV66385717; called by muse, mutect2, varscan2
- CER1 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV66602840, COSV66603341; called by muse, mutect2, varscan2
- CERKL | c.1540G>A p.E514K (on ENST00000339098 / NM_001030311.2; = p.E488K on NM_201548.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV59202412; called by mutect2, varscan2
- CHD4 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV58893710; called by muse, mutect2, varscan2
- CHD8 | c.2269G>C p.E757Q (on ENST00000646647 / NM_001170629.2; = p.E478Q on NM_020920.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101303110, COSV67869484, COSV67872487; called by muse, mutect2, varscan2
- CHRNB4 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.958); catalogued as COSV55714431; called by muse, mutect2
- CHSY1 | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.821); catalogued as COSV54251121; called by muse, mutect2
- CLIP1 | c.4008G>C p.K1336N (on ENST00000620786 / NM_001247997.1; = p.K1325N on NM_002956.2) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV56796586; called by muse, mutect2
- CNTN3 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV55161799; called by muse, mutect2, varscan2
- CNTRL | c.2827G>C p.E943Q | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53042543, COSV99443778; called by muse, mutect2, varscan2
- COG8 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV54741578; called by muse, mutect2, varscan2
- COL11A1 | c.2601A>T p.K867N | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62171297; called by muse, mutect2, varscan2
- COL12A1 | c.6650G>T p.W2217L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.372); catalogued as COSV59388504; called by muse, mutect2, varscan2
- COL12A1 | c.6565G>T p.D2189Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59388517; called by muse, mutect2, varscan2
- COL18A1 | c.3964G>A p.E1322K (on ENST00000359759 / NM_130444.3; = p.E1087K on NM_030582.4) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.623); catalogued as COSV60586045; called by muse, mutect2, varscan2
- COL3A1 | c.3590G>T p.C1197F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.497); catalogued as COSV58581159; called by muse, mutect2, varscan2
- COL5A2 | c.3116C>G p.S1039C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV66406624; called by muse, mutect2
- COQ8A | c.1578C>G p.I526M | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62001097; called by muse, mutect2, varscan2
- CR1L | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 106/481 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54322181; called by muse, mutect2, varscan2
- CRISP1 | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.044); catalogued as COSV59992566; called by muse, mutect2, varscan2
- CSMD1 | c.3662C>A p.P1221Q (on ENST00000520002; = p.P1220Q on NM_033225.6) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777083383, COSV59276597, COSV59310638; called by muse, mutect2, varscan2
- CTNNA2 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58131547; called by muse, mutect2, varscan2
- CTNNA2 | c.2575-1G>T p.X859_splice (on ENST00000402739 / NM_001282597.3; = p.X811_splice on NM_004389.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 32/100 reads (32%) | catalogued as COSV58131567; called by muse, mutect2, varscan2
- CYB5RL | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258728795, COSV55276430; called by muse, mutect2, varscan2
- CYP2S1 | c.1437T>A p.S479R | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV59504880; called by muse, mutect2, varscan2
- CYP7A1 | c.1183C>A p.H395N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184962029, COSV56962035; called by muse, mutect2, varscan2
- DARS2 | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.022); catalogued as COSV99508593; called by muse, mutect2
- DCLK3 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV69362105; called by muse, mutect2, varscan2
- DDR1 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV61318468; called by muse, mutect2
- DENND2A | c.1395C>G p.F465L | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754210561, COSV52046974, COSV52053714, COSV99326088; called by muse, mutect2
- DHX9 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as rs1357041306, COSV62358042; called by muse, mutect2
- DIPK2B | c.1256G>C p.R419T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV67640796; called by muse, mutect2, varscan2
- DLG5 | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64946502; called by muse, mutect2
- DMBT1 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV57532673; called by muse, mutect2, varscan2
- DMD | c.8003C>G p.A2668G | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV58888821; called by muse, mutect2, varscan2
- DNAH9 | c.8580C>G p.F2860L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52331662; called by muse, mutect2, varscan2
- DNAJC28 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58721153; called by muse, mutect2
- DOCK10 | c.2920C>A p.L974I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.622); catalogued as COSV51346716; called by muse, mutect2, varscan2
- DOK1 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV51206016, COSV51209312; called by muse, mutect2, varscan2
- DOK5 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.981); catalogued as COSV52815853; called by muse, mutect2, varscan2
- DPAGT1 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62613876; called by muse, mutect2, varscan2
- DSCAM | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68019945, COSV68025940; called by muse, mutect2, varscan2
- DSE | c.2844G>C p.W948C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.005); catalogued as COSV100528799, COSV59061386; called by mutect2, varscan2
- DSPP | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV56807314, COSV99217455; called by muse, mutect2, varscan2
- DUSP22 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV60523071; called by muse, mutect2, varscan2
- DYRK1A | c.1768C>A p.H590N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV58703369; called by muse, varscan2
- EEF1B2 | c.398-1G>A p.X133_splice | Splice Site (SNP) | VAF 16/160 reads (10%) | catalogued as rs1286150186, COSV51909414, COSV99260705; called by muse, mutect2, varscan2
- EGR1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV53517741; called by muse, mutect2, varscan2
- EOMES | c.1760C>G p.A587G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.108); catalogued as COSV55410628; called by muse, mutect2, varscan2
- EP400 | c.8277G>T p.Q2759H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV57761406; called by muse, mutect2, varscan2
- EPHA8 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs929755154, COSV51262230, COSV99385278; called by muse, mutect2, varscan2
- ESYT1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs745566246, COSV57271319; called by muse, mutect2, varscan2
- EXT1 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.824); catalogued as COSV65474326; called by muse, mutect2, varscan2
- FAM151A | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56362827; called by muse, mutect2, varscan2
- FAM171B | c.2320C>A p.H774N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.187); catalogued as COSV59000289; called by muse, mutect2, varscan2
- FAM47B | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV61452249; called by muse, mutect2, varscan2
- FAM50B | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66654425; called by muse, mutect2, varscan2
- FAM78B | c.709C>G p.P237A | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57974801; called by muse, mutect2, varscan2
- FANCM | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as COSV53531087, COSV53532502; called by muse, mutect2, varscan2
- FANCM | c.3545T>A p.L1182H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.936); catalogued as COSV57496764; called by muse, mutect2, varscan2
- FAT2 | c.12607C>G p.L4203V | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55812300, COSV99943495; called by muse, mutect2
- FAT4 | c.11980G>A p.D3994N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58669639; called by muse, mutect2, varscan2
- FBXO42 | c.2148G>C p.K716N | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV65044360; called by muse, mutect2, varscan2
- FERMT3 | c.1189G>A p.D397N (on ENST00000279227 / NM_178443.3; = p.D393N on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.22); catalogued as rs1451573592, COSV54176666; called by muse, mutect2, varscan2
- FEZ1 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV54026386, COSV99630172; called by muse, mutect2, varscan2
- FGFBP1 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV52585998; called by muse, mutect2
- FHOD3 | c.2282C>A p.S761Y (on ENST00000359247 / NM_001281739.3; = p.S778Y on NM_025135.5) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.188); catalogued as COSV57162889, COSV57169913; called by muse, mutect2
- FLOT1 | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV64507930; called by muse, mutect2
- FN1 | c.5975-1G>C p.X1992_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100116724; called by muse, mutect2
- FOXA3 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs780181879, COSV56214978; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs377454541; called by muse, varscan2
- FPGT-TNNI3K | c.1505G>C p.W502S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58544234; called by muse, varscan2
- GAS2L3 | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1257702259, COSV57155797; called by muse, mutect2, varscan2
- GBP7 | c.998A>T p.H333L | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV54007884; called by muse, mutect2, varscan2
- GBP7 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as rs779459312, COSV54007898; called by muse, mutect2, varscan2
- GEMIN7 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.117); catalogued as COSV54319041; called by muse, mutect2, varscan2
- GEMIN7 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV54319056; called by muse, mutect2, varscan2
- GLUD1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 44/172 reads (26%) | catalogued as COSV53277161; called by muse, mutect2, varscan2
- GMDS | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66428094; called by muse, mutect2, varscan2
- GNA14 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV59017883; called by muse, mutect2, varscan2
- GPALPP1 | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV62705315; called by muse, mutect2, varscan2
- GPATCH2L | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV55046393; called by muse, mutect2, varscan2
- GPR45 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV51522575; called by muse, mutect2, varscan2
- GRIK1 | c.1737G>A p.W579* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV58709375; called by muse, mutect2, varscan2
- GSTM5 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV56656406; called by muse, mutect2, varscan2
- GTDC1 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.319); catalogued as rs1172402016, COSV53987459, COSV53998471; called by muse, mutect2, varscan2
- HBP1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV56016728; called by muse, mutect2, varscan2
- HECTD4 | c.7492G>A p.E2498K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV66386011; called by muse, mutect2, varscan2
- HHIPL2 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.233); catalogued as COSV58562969; called by muse, mutect2
- HLA-E | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV64927164; called by muse, mutect2, varscan2
- HUWE1 | c.9202G>C p.D3068H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV53332863; called by muse, varscan2
- IDH3B | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100250019; called by muse, mutect2, varscan2
- IGFL2 | c.244G>A p.D82N (on ENST00000377693 / NM_001135113.2; = p.D93N on NM_001002915.2) | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV66616557, COSV66616579; called by muse, mutect2
- IL17A | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as COSV60683803; called by muse, mutect2, varscan2
- INSRR | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs868120562, COSV100948096, COSV63870623; called by muse, mutect2, varscan2
- INTS7 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV65343587; called by muse, varscan2
- IPO9 | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1359506247, COSV64232678; called by muse, mutect2, varscan2
- IQCG | c.872T>C p.L291S | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54559960; called by muse, mutect2, varscan2
- ITGB4 | c.5094G>C p.E1698D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52321297; called by muse, mutect2
- ITGB6 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV51790367; called by muse, mutect2, varscan2
- ITGBL1 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66004695; called by muse, mutect2, varscan2
- ITPRIP | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53390104; called by muse, mutect2, varscan2
- JHY | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV57072386; called by muse, mutect2, varscan2
- KANSL1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369793673; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KANSL1L | c.1702T>C p.F568L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV55989099; called by muse, mutect2, varscan2
- KAT14 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66606435; called by muse, mutect2, varscan2
- KBTBD8 | c.1276G>C p.A426P | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55126247; called by muse, mutect2, varscan2
- KCNAB1 | c.409G>C p.D137H (on ENST00000490337 / NM_172160.3; = p.D126H on NM_003471.3) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56740340, COSV56742479; called by muse, mutect2
- KCNG1 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.166); catalogued as rs755946302, COSV65367874; called by muse, mutect2, varscan2
- KDF1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV57670755, COSV57671293; called by muse, mutect2, varscan2
- KDM1A | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs1239941955, COSV63086422, COSV63087608; called by muse, mutect2, varscan2
- KIAA0100 | c.3777C>G p.I1259M | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66490267; called by muse, mutect2
- KIAA1210 | c.2053C>T p.L685F | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV68175237; called by muse, mutect2, varscan2
- KIF17 | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.343); catalogued as COSV56115267; called by muse, mutect2, varscan2
- KIF9 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV55517358; called by muse, varscan2
- KLB | c.2530G>C p.D844H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV57299822; called by muse, mutect2, varscan2
- KLHL38 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV58085815; called by muse, mutect2, varscan2
- KLK1 | c.780G>C p.E260D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56825707, COSV56825845; called by muse, mutect2
- KNTC1 | c.3588C>G p.F1196L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV61078630; called by muse, mutect2, varscan2
- KRT4 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs377329227, COSV53409461; ClinVar: benign; called by muse, mutect2, varscan2
- L3MBTL3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV62384040; called by muse, mutect2, varscan2
- LAMA2 | c.7858G>A p.D2620N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70337004; called by muse, mutect2, varscan2
- LAMC2 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM062816, COSV51452016, COSV51458940; called by muse, mutect2
- LARP1B | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV52793858, COSV52795197; called by muse, mutect2
- LCOR | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | catalogued as COSV53714198; called by muse, mutect2, varscan2
- LILRA1 | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV52177404, COSV52184878; called by muse, mutect2, varscan2
- LILRB2 | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as COSV58743269; called by muse, mutect2, varscan2
- LINGO2 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as rs1421505186, COSV58056363; called by muse, mutect2, varscan2
- LRIG2 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV63160604; called by muse, mutect2, varscan2
- LRP1 | c.8533G>C p.D2845H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54500836; called by muse, mutect2
- LRP12 | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV52624986, COSV52626773; called by muse, mutect2
- LRP1B | c.12606del p.I4203Lfs*11 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as COSV101257985, COSV67211657; called by mutect2, pindel*, varscan2
- LRP1B | c.5095G>T p.A1699S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1406922263, COSV67181989; called by muse, mutect2, varscan2
- LRP1B | c.2519C>A p.A840E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs946435404, COSV63341547; called by muse, mutect2, varscan2
- LRRC25 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59114615, COSV59114806; called by muse, mutect2, varscan2
- LRRIQ3 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs780829903, COSV63040591, COSV63040720, COSV63042630; called by muse, mutect2, varscan2
- LTBP1 | c.4647G>T p.E1549D (on ENST00000404816 / NM_206943.4; = p.E1223D on NM_000627.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55374910; called by muse, varscan2
- MAGEA8 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54063540; called by muse, mutect2, varscan2
- MAMDC4 | c.2551G>C p.E851Q (on ENST00000445819; = p.E772Q on NM_206920.3) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.952); catalogued as COSV56374541; called by muse, mutect2
- MAP2K5 | c.328A>C p.K110Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV51609302; called by muse, mutect2
- MAP2K5 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV51609321; called by muse, mutect2
- MARCHF10 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.573); catalogued as COSV60884835; called by muse, mutect2, varscan2
- MCCC1 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as CM125737, COSV55605978; called by muse, mutect2, varscan2
- MCF2L2 | c.1878C>G p.D626E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as COSV61048371; called by muse, mutect2
- MCM4 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV100031390, COSV50621315; called by muse, varscan2
- MED12 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99048840; called by muse, mutect2, varscan2
- MED12 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs1057524478, COSV61354558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MELTF | c.645-2A>G p.X215_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV56378427; called by muse, mutect2, varscan2
- METTL16 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); catalogued as COSV54011579; called by muse, mutect2, varscan2
- MGA | c.3217C>T p.R1073* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV54947714; called by muse, mutect2, varscan2
- MICAL3 | c.5909T>C p.L1970P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52810962; called by muse, mutect2, varscan2
- MIGA1 | c.1329G>C p.Q443H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV66222547; called by muse, mutect2
- MKI67 | c.5507G>C p.R1836T | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV64072278; called by muse, mutect2
- MORC4 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55239002; called by muse, mutect2, varscan2
- MTMR7 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV51662682, COSV51663182; called by muse, mutect2, varscan2
- MTX1 | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as COSV57425609; called by muse, mutect2, varscan2
- MYH1 | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56843025; called by muse, mutect2, varscan2
- MYH8 | c.4252G>C p.E1418Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV67959115; called by muse, mutect2, varscan2
- MYOM3 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV58389045; called by muse, mutect2, varscan2
- NAMPT | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV55993985; called by muse, mutect2, varscan2
- NCF2 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV62314731; called by muse, mutect2, varscan2
- NCSTN | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV54097220; called by muse, mutect2, varscan2
- NES | c.4714G>C p.E1572Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV63960247; called by muse, mutect2, varscan2
- NFATC3 | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1425352792, COSV60470415; called by muse, mutect2, varscan2
- NKTR | c.1592G>C p.G531A | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as COSV51768998; called by muse, mutect2, varscan2
- NOX1 | c.1356G>C p.L452F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV54192806; called by muse, mutect2, varscan2
- NR2E3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV58907006, COSV58907828; called by muse, mutect2, varscan2
- NSD1 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1403785225, COSV61769973; called by muse, mutect2, varscan2
- OLR1 | c.370C>G p.H124D | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV58870772; called by muse, mutect2
- OR10G7 | c.412C>A p.R138S | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs746856435, COSV100389830, COSV57865473, COSV57865543; called by muse, mutect2, varscan2
- OR11L1 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63313440, COSV63313745; called by muse, mutect2, varscan2
- OR2A1 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs1356225696, COSV68822643; called by muse, mutect2, varscan2
- OR2B6 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55128276; called by muse, mutect2, varscan2
- OR2T33 | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV58813622; called by muse, varscan2
- OR4A16 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); catalogued as rs779330023, COSV59041722; called by muse, mutect2, varscan2
- OR51G1 | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58968255, COSV58969891; called by muse, mutect2, varscan2
- OR5A1 | c.867C>A p.N289K | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57375582; called by muse, mutect2, varscan2
- OR5D13 | c.283T>A p.S95T | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV62332592; called by muse, mutect2, varscan2
- OR5H1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV63401632; called by muse, mutect2, varscan2
- OTOA | c.3115G>T p.E1039* (on ENST00000286149; = p.E1025* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 26/207 reads (13%) | catalogued as COSV99624112; called by muse, mutect2, varscan2
- PAPSS2 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63262345; called by muse, mutect2
- PBX3 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV60730066; called by muse, mutect2, varscan2
- PCDHA8 | c.1169T>A p.M390K | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65334550; called by muse, mutect2
- PCDHB6 | c.1460C>G p.S487W | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50689487; called by muse, mutect2, varscan2
- PCDHGA6 | c.1647C>A p.S549R | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as rs763067110, COSV99534650; called by muse, varscan2
- PCDHGA6 | c.1648C>A p.L550M | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99534658; called by muse, varscan2
- PCDHGA7 | c.1830G>T p.K610N | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV53892085, COSV99545549; called by muse, mutect2, varscan2
- PCNX2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1180725355, COSV50780665; called by muse, mutect2, varscan2
- PDE3A | c.3067C>A p.P1023T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62966920; called by muse, mutect2, varscan2
- PELI3 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV57855946; called by muse, mutect2, varscan2
- PHF14 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.055); catalogued as COSV68853950; called by muse, mutect2
- PITPNM3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52592620; called by muse, mutect2, varscan2
- PKD1L2 | c.1850G>A p.R617K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs957254810, COSV55157550; called by muse, mutect2, varscan2
- PLCH2 | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs755926522, COSV53938674; called by muse, mutect2, varscan2
- PLCL1 | c.2069G>C p.G690A | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.268); catalogued as COSV70820480; called by muse, mutect2
- PLD3 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1349776061, COSV62924077; called by muse, mutect2, varscan2
- PLPPR5 | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54168338; called by muse, mutect2, varscan2
- POLR3E | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.644); catalogued as COSV55398696; called by muse, mutect2
- PPIAL4G | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as COSV70086714; called by muse, mutect2, varscan2
- PRMT5 | c.1443C>A p.Y481* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53544672; called by muse, mutect2, varscan2
- PRR19 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV56623587; called by muse, mutect2, varscan2
- PTAFR | c.425G>T p.W142L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59535866; called by muse, mutect2, varscan2
- PTPDC1 | c.832G>T p.E278* (on ENST00000375360 / NM_177995.3; = p.E330* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as rs1344941514, COSV56621036; called by muse, mutect2, varscan2
- PTPN18 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV51557814; called by muse, mutect2
- PTPRC | c.332C>A p.T111K | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs747055380, COSV61405623; called by muse, mutect2, varscan2
- PTPRS | c.5739G>C p.K1913N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53608440; called by muse, mutect2
- RALGAPB | c.3498C>G p.F1166L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53433931; called by muse, mutect2
- RANBP6 | c.2512G>C p.D838H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52387994; called by muse, mutect2, varscan2
- RAPGEF3 | c.1111C>G p.Q371E (on ENST00000389212; = p.Q329E on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as COSV50197830; called by muse, mutect2
- RASAL2 | c.2438G>A p.R813K | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62708431; called by muse, mutect2, varscan2
- RB1 | c.1328C>G p.S443* | Nonsense Mutation (SNP) | VAF 26/47 reads (55%) | catalogued as CM034900, COSV57294225, COSV57294594, COSV57318875; called by muse, mutect2, varscan2
- RBM27 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54586846; called by muse, mutect2
- RBSN | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456941640, COSV53791297; called by muse, mutect2, varscan2
- REG1B | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59304180; called by muse, varscan2
- RESF1 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57019269; called by muse, mutect2, varscan2
- RHBDF1 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV51953325; called by muse, mutect2, varscan2
- RINT1 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57557055; called by muse, mutect2, varscan2
- RLF | c.4572G>C p.K1524N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV65650378; called by muse, mutect2
- ROBO2 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV59893689; called by muse, mutect2
- RPGRIP1 | c.3058G>T p.E1020* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV52843800; called by muse, mutect2, varscan2
- RTN1 | c.242-1G>T p.X81_splice | Splice Site (SNP) | VAF 28/82 reads (34%) | catalogued as COSV50718427, COSV99956914; called by muse, varscan2
- RYR2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV63657381; called by muse, mutect2, varscan2
- RYR3 | c.13958A>T p.K4653M (on ENST00000389232; = p.K4654M on NM_001036.6) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66776091, COSV66791564; called by muse, mutect2, varscan2
- SALL4 | c.2291C>A p.S764Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1235769529, COSV53849515, COSV53850460; called by muse, mutect2, varscan2
- SCN3A | c.4561G>C p.D1521H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV51800371, COSV51800627; called by muse, mutect2, varscan2
- SCN9A | c.2072G>T p.S691I (on ENST00000303354; = p.S680I on NM_002977.3) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100312132; called by muse, mutect2, varscan2
- SCN9A | c.2071A>G p.S691G (on ENST00000303354; = p.S680G on NM_002977.3) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100312135; called by muse, mutect2, varscan2
- SCRN1 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV54128033; called by muse, mutect2
- SERPINA9 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV54072368; called by muse, mutect2, varscan2
- SEZ6L2 | c.1444C>T p.R482C (on ENST00000308713 / NM_001114099.3; = p.R412C on NM_012410.4) | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs1466762799, COSV58096772; called by muse, mutect2, varscan2
- SFTPB | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs1459557284, COSV60892539; called by muse, mutect2, varscan2
- SGIP1 | c.1547G>T p.S516I | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52762056; called by muse, mutect2, varscan2
- SH3PXD2A | c.2188G>T p.G730C (on ENST00000369774 / NM_001365079.1; = p.G702C on NM_014631.2) | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV60115276; called by muse, mutect2, varscan2
- SHPK | c.605G>C p.W202S | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56647980; called by muse, mutect2, varscan2
- SIGLEC8 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs759003380, COSV58471624; called by muse, mutect2, varscan2
- SIRT1 | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV53016786; called by muse, mutect2, varscan2
- SLC23A3 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55405432; called by muse, mutect2, varscan2
- SLC25A11 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs767678115, COSV52590222; called by muse, mutect2, varscan2
- SLC25A25 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs1226859476, COSV66089743; called by muse, mutect2, varscan2
- SLC25A32 | c.680A>T p.Y227F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV52566493; called by muse, mutect2
- SLC44A5 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV63757824; called by muse, mutect2
- SLC4A4 | c.1048G>A p.D350N (on ENST00000264485 / NM_001098484.3; = p.D306N on NM_003759.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52613421; called by muse, mutect2, varscan2
- SLC7A8 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57552858; called by muse, mutect2
- SLC9C2 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100876667; called by mutect2, varscan2
- SLITRK1 | c.1860G>T p.L620F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1186130397, COSV65673971, COSV65675608; called by muse, mutect2, varscan2
- SMARCA2 | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV61804308; called by muse, mutect2
- SMC5 | c.2079G>C p.K693N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV63191377; called by muse, mutect2, varscan2
- SMOX | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV53862590; called by muse, mutect2, varscan2
- SMU1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.052); catalogued as COSV68139447; called by muse, mutect2, varscan2
- SMYD3 | c.1017C>G p.I339M (on ENST00000490107 / NM_001375962.1; = p.I280M on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV63625356; called by muse, mutect2, varscan2
- SNX27 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV64325375; called by muse, mutect2, varscan2
- SOX7 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV58730170; called by muse, mutect2, varscan2
- SP1 | c.1642C>T p.Q548* (on ENST00000327443 / NM_138473.3; = p.Q541* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | catalogued as COSV59401640; called by muse, mutect2, varscan2
- SPDYE5 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as rs1554482340, COSV71595994; called by muse, mutect2, varscan2
- SPHKAP | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV60867318; called by muse, mutect2
- SPOPL | c.592A>T p.R198* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV54511401; called by muse, mutect2, varscan2
- SPSB1 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60161793; called by muse, mutect2
- SPSB4 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs768999377, COSV60144515, COSV60145595; called by muse, mutect2, varscan2
- SPTA1 | c.3040T>A p.W1014R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63748142; called by muse, mutect2
- SRRM2 | c.7604C>T p.S2535L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs772258149, COSV51939644, COSV51940393; called by muse, mutect2, varscan2
- SYDE2 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs765959082, COSV52313733; called by muse, mutect2, varscan2
- SYNE2 | c.18520G>C p.E6174Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100647087, COSV59938250; called by muse, mutect2, varscan2
- TATDN2 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764786371, COSV55050245, COSV55051810; called by muse, mutect2, varscan2
- TBX18 | c.884C>G p.A295G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV63735907; called by muse, mutect2, varscan2
- TC2N | c.63C>G p.H21Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61746108; called by muse, mutect2, varscan2
- TCHHL1 | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV64284714, COSV64286831; called by muse, mutect2, varscan2
- THADA | c.5350G>T p.V1784F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs201032063, COSV57674959; called by muse, varscan2
- THAP4 | c.476A>C p.Q159P | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV67190501; called by muse, mutect2, varscan2
- TJP2 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs757972142, COSV55262131; called by muse, mutect2, varscan2
- TLN1 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59203540; called by muse, mutect2, varscan2
- TMEM168 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs1214083496, COSV100454802, COSV57179032; called by muse, mutect2, varscan2
- TMEM201 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61050652; called by muse, mutect2, varscan2
- TNFRSF25 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV61067472; called by muse, mutect2, varscan2
- TNFSF18 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 20/177 reads (11%) | catalogued as COSV53439556; called by muse, mutect2, varscan2
- TNR | c.3637G>C p.D1213H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54867728; called by mutect2, varscan2
- TP53 | c.936del p.S313Afs*32 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as CD165594, COSV52772076, COSV53210453; called by mutect2, pindel, varscan2
- TPI1 | c.546C>G p.F182L (on ENST00000229270; = p.F145L on NM_000365.6) | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as COSV51289938, COSV51289967; called by muse, mutect2, varscan2
- TRIM14 | c.472A>T p.M158L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58353079; called by muse, mutect2, varscan2
- TRIM54 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV56081816; called by muse, varscan2
- TRPV5 | c.837C>A p.D279E | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV54682739; called by muse, mutect2, varscan2
- TRPV6 | c.1619T>C p.V540A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63890230; called by muse, mutect2, varscan2
- TSGA10IP | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV56709817; called by muse, mutect2, varscan2
- TSPAN2 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.371); catalogued as rs777331815, COSV65689416; called by mutect2, varscan2
- TSPAN33 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.701); catalogued as rs761393558, COSV56825233; called by muse, mutect2, varscan2
- TTN | c.54625G>A p.E18209K (on ENST00000591111; = p.E10785K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/224 reads (10%) | PolyPhen benign (0.415); catalogued as COSV59861923; called by muse, varscan2
- TTN | c.50324G>A p.G16775E (on ENST00000591111; = p.G9351E on NM_003319.4) | Missense Mutation (SNP) | VAF 38/126 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV59861982, COSV59904239; called by muse, mutect2, varscan2
- UBR4 | c.9937G>A p.E3313K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV64382064; called by muse, mutect2, varscan2
- UGGT2 | c.4008+1G>T p.X1336_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as COSV65071851, COSV65074019; called by muse, mutect2, varscan2
- UGT2B28 | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59430312; called by muse, varscan2
- UHRF1BP1 | c.824C>G p.A275G | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV51952320; called by muse, mutect2, varscan2
- UNC13C | c.2526T>A p.N842K | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV52839819; called by muse, mutect2, varscan2
- UNC5D | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV54765975; called by muse, mutect2, varscan2
- UPRT | c.345G>C p.M115I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV64912057, COSV64912414; called by muse, varscan2
- UQCC1 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV62901726; called by muse, mutect2, varscan2
- URB2 | c.1653C>G p.F551L | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV50980974; called by muse, mutect2, varscan2
- UROC1 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52029620, COSV52038435; called by muse, mutect2, varscan2
- USE1 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55726599, COSV55728684; called by muse, mutect2
- USH2A | c.13950G>T p.Q4650H | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as COSV56321753; called by muse, mutect2, varscan2
- USH2A | c.9537C>G p.I3179M | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100228466, COSV56321766; called by muse, mutect2, varscan2
- USP26 | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63707940; called by muse, mutect2, varscan2
- USP53 | c.1307A>T p.D436V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1432403506, COSV56791966; called by muse, mutect2, varscan2
- UTRN | c.10237G>C p.E3413Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100838700, COSV62306870; called by muse, mutect2
- VHLL | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as COSV100372674, COSV60554020; called by muse, mutect2, varscan2
- XDH | c.1175G>C p.G392A | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as COSV65146644; called by muse, mutect2, varscan2
- XRCC1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747404541, COSV53446991; called by muse, mutect2, varscan2
- YPEL2 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.925); catalogued as COSV57070292; called by muse, mutect2, varscan2
- ZAN | c.5931G>C p.E1977D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV61804262; called by muse, mutect2, varscan2
- ZBED1 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV58129632; called by muse, mutect2, varscan2
- ZBED2 | c.423G>C p.R141S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV51912173; called by muse, mutect2, varscan2
- ZBTB16 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60088717; called by muse, mutect2, varscan2
- ZC3H12C | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV53708163, COSV53710803; called by muse, mutect2
- ZDBF2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV65621272; called by muse, mutect2, varscan2
- ZFP90 | c.826C>G p.H276D | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68050552; called by muse, mutect2, varscan2
- ZFPM2 | c.2026C>A p.P676T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV101023112, COSV101023323; called by muse, varscan2
- ZFPM2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV65875978, COSV99059178; called by muse, mutect2, varscan2
- ZNF224 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV61241392, COSV61242681; called by muse, mutect2, varscan2
- ZNF395 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs761620777, COSV60427615; called by muse, mutect2, varscan2
- ZNF41 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV100492276, COSV57440781; called by muse, mutect2, varscan2
- ZNF496 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1224689027, COSV54173051, COSV54178006; called by muse, mutect2, varscan2
- ZNF513 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.61); catalogued as COSV52006122; called by muse, mutect2, varscan2
- ZNF536 | c.2168C>G p.S723* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs1448856950, COSV100835538, COSV62817472; called by muse, mutect2, varscan2
- ZNF567 | c.1124G>T p.R375L (on ENST00000536254 / NM_001322913.1; = p.R344L on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV62444002, COSV62446394; called by muse, mutect2, varscan2
- ZNF578 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.103); catalogued as COSV101405052, COSV69735858; called by muse, mutect2, varscan2
- ZNF644 | c.149C>G p.S50* | Nonsense Mutation (SNP) | VAF 34/146 reads (23%) | catalogued as COSV61345679; called by muse, mutect2, varscan2
- ZNFX1 | c.3109C>G p.R1037G | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV65573265, COSV65578802; called by muse, mutect2, varscan2
- ATP8B3 | c.1143_1150del p.V382Dfs*144 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- FAM221B | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.158); called by muse, mutect2
- KDM6A | c.1965dup p.G656Wfs*2 | Frame Shift Ins (INS) | VAF 14/29 reads (48%) | called by mutect2, varscan2
- MFSD2A | c.1382del p.L461Pfs*23 (on ENST00000372809 / NM_001136493.3; = p.L448Pfs*23 on NM_032793.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- MMP16 | c.1307del p.P436Lfs*31 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- NDUFS2 | c.943del p.E315Sfs*27 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- NYAP1 | c.1703_1705delinsTT p.K568Ifs*6 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2*
- OR52A5 | c.888_889del p.V297Efs*7 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- PIK3AP1 | c.822del p.N275Mfs*27 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.944A>T p.H315L | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PRAMEF7 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.81); called by muse, mutect2
- SNX29P2 | n.497G>T | Splice Region (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1304A>T p.D435V | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by mutect2, varscan2
- TECPR1 | c.355del p.E119Sfs*78 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- ABCA1 | c.6132C>T p.N2044= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV66063358; called by muse, mutect2, varscan2
- ABCD2 | c.2190G>C p.L730= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV58049050; called by muse, mutect2
- AC004922.1 | c.1638G>C p.G546= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV53162528, COSV99403074; called by muse, mutect2, varscan2
- ADGRB3 | c.2922T>A p.I974= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV53232926; called by muse, mutect2, varscan2
- AHNAK2 | c.7647G>A p.V2549= | Silent (SNP) | VAF 17/276 reads (6%) | catalogued as COSV60906422; called by muse, mutect2
- AKAP6 | c.345T>G p.S115= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV55203159; called by muse, mutect2, varscan2
- AKT3 | c.765T>C p.I255= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV55605690; called by muse, mutect2, varscan2
- AP2A2 | c.189C>T p.L63= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs373083307; called by muse, mutect2, varscan2
- AR | c.135G>C p.A45= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV65952471; called by muse, varscan2
- ARAP2 | c.1755T>C p.V585= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV58281858; called by muse, mutect2, varscan2
- ARPP21 | c.1989C>T p.N663= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs550779254, COSV51791188; called by muse, mutect2, varscan2
- ASPA | c.726C>T p.I242= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as COSV53979779; called by muse, mutect2, varscan2
- B3GNT8 | c.57C>G p.L19= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV54195313; called by muse, mutect2
- BATF | c.258G>A p.L86= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54375170, COSV99708728; called by muse, mutect2, varscan2
- C1orf56 | c.255C>G p.L85= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV54845551; called by muse, mutect2, varscan2
- CACNG8 | c.570G>A p.P190= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV54413529; called by muse, varscan2
- CASP6 | c.516C>T p.V172= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1287450402, COSV99488629; called by muse, mutect2, varscan2
- CDK12 | c.2274G>A p.V758= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs770270328, COSV70999039; called by muse, mutect2, varscan2
- CEACAM20 | c.1491G>A p.E497= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs368515417; called by muse, varscan2
- CNTNAP5 | c.1164G>C p.G388= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV70469875, COSV70475480; called by muse, mutect2, varscan2
- CPZ | c.975C>T p.F325= (on ENST00000360986 / NM_001014447.3; = p.F314= on NM_003652.3) | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV59921330; called by muse, mutect2, varscan2
- CSMD2 | c.6897C>T p.I2299= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1368543703, COSV53874238; called by muse, mutect2, varscan2
- CTH | c.33C>T p.F11= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV61007242; called by muse, mutect2, varscan2
- CTSK | c.972C>T p.A324= | Silent (SNP) | VAF 74/253 reads (29%) | catalogued as COSV55010620; called by muse, mutect2, varscan2
- CUX2 | c.1818G>A p.K606= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV55622862; called by muse, mutect2, varscan2
- DNAH10 | c.3381G>A p.V1127= (on ENST00000409039; = p.V1066= on NM_207437.3) | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV68987160; called by muse, mutect2
- DNAH3 | c.7215C>T p.S2405= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV54500863; called by muse, mutect2
- DPF1 | c.408T>A p.G136= | Silent (SNP) | VAF 11/192 reads (6%) | catalogued as COSV62791853; called by muse, mutect2
- DUSP4 | c.846G>T p.A282= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs141546461, COSV53544537; called by muse, mutect2, varscan2
- DYNAP | c.357C>G p.L119= (on ENST00000321600; = p.L93= on NM_173629.3) | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as COSV58665896, COSV58665906; called by muse, varscan2
- DYRK1A | c.1731C>T p.V577= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV58703364; called by muse, varscan2
- ENOSF1 | c.375C>G p.L125= (on ENST00000340116 / NM_001354066.2; = p.L77= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/340 reads (20%) | catalogued as COSV51890163; called by muse, mutect2, varscan2
- EPB41L5 | c.1362G>A p.L454= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV55348270; called by muse, varscan2
- EPHA7 | c.408G>A p.R136= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs1397442418, COSV65168457; called by muse, mutect2, varscan2
- ESR1 | c.60G>C p.G20= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52780782; called by muse, mutect2, varscan2
- EVL | c.189T>C p.Y63= (on ENST00000402714 / NM_001330221.2; = p.Y65= on NM_016337.3) | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs1161121031, COSV67374117; called by muse, mutect2, varscan2
- EXOC7 | c.81C>T p.F27= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1488614149, COSV58738934; called by mutect2, varscan2
- FAAH | c.834C>G p.L278= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV54542856; called by muse, mutect2
- FABP1 | c.276G>A p.V92= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV55557666; called by muse, mutect2, varscan2
- FAXDC2 | c.351C>T p.V117= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs755183405, COSV58171181; called by muse, mutect2, varscan2
- FBN1 | c.5784T>C p.C1928= | Silent (SNP) | VAF 45/64 reads (70%) | catalogued as COSV57308055; called by muse, mutect2, varscan2
- FREM2 | c.3639C>G p.L1213= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as COSV54826745; called by muse, mutect2, varscan2
- GJC1 | c.96G>C p.R32= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV57910317, COSV57911623; called by muse, mutect2, varscan2
- GPR179 | c.768C>G p.L256= | Silent (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- GRID1 | c.348C>G p.V116= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1180658622, COSV100021695, COSV60011868; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1926C>T p.F642= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100736398; called by mutect2, varscan2
- GTF3C1 | c.5775A>G p.A1925= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as COSV62238541; called by muse, mutect2, varscan2
- H2BC12 | c.48G>A p.K16= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs546707387, COSV63616586, COSV63617626; called by muse, mutect2
- HBG2 | c.183C>T p.V61= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV57962835; called by muse, mutect2, varscan2
- HOMER2 | c.465C>T p.A155= (on ENST00000304231 / NM_199330.3; = p.A144= on NM_004839.4) | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as rs370161333; called by muse, mutect2, varscan2
- HTT | c.8430C>G p.L2810= | Silent (SNP) | VAF 50/147 reads (34%) | catalogued as COSV61856718; called by muse, mutect2, varscan2
- HUWE1 | c.9144G>A p.Q3048= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV53332889, COSV53343427; called by muse, varscan2
- IDH3B | c.621G>A p.K207= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV61388548; called by muse, mutect2
- IGKV1-16 | c.108T>C p.S36= | Silent (SNP) | VAF 58/229 reads (25%) | called by muse, mutect2, varscan2
- IMPDH1 | c.522C>T p.L174= (on ENST00000470772 / NM_001142573.2; = p.L260= on NM_000883.4) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV58314760, COSV58315986; called by muse, mutect2, varscan2
- IRAK3 | c.1026A>G p.P342= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1435726128, COSV54159056; called by muse, mutect2, varscan2
- KCND3 | c.765C>T p.I255= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1557767443, COSV56174087; called by muse, mutect2
- KCNT2 | c.999G>A p.V333= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs1203351447, COSV54061952; called by muse, mutect2, varscan2
- KIAA1614 | c.2556C>G p.L852= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV62550310; called by muse, mutect2, varscan2
- KIF1B | c.4602C>T p.L1534= (on ENST00000377086 / NM_001365952.1; = p.L1488= on NM_015074.3) | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV55802749; called by muse, mutect2, varscan2
- KLF10 | c.951C>T p.V317= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs1169858155, COSV53434668; called by muse, mutect2
- KRTAP5-9 | c.99C>A p.P33= | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as COSV73200136, COSV73200159; called by muse, mutect2, varscan2
- LBP | c.1206G>T p.L402= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV54138401; called by muse, mutect2
- LEP | c.303G>A p.L101= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV58240588; called by muse, mutect2, varscan2
- LOXL3 | c.1332C>T p.L444= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV51206013; called by muse, mutect2, varscan2
- LRP1 | c.2667C>T p.L889= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV54500824, COSV54517508; called by muse, mutect2, varscan2
- MLIP | c.426A>T p.A142= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV51425236; called by muse, mutect2
- MSI1 | c.354G>A p.V118= | Silent (SNP) | VAF 64/198 reads (32%) | catalogued as COSV57455131; called by muse, mutect2, varscan2
- MUC4 | c.16086G>A p.L5362= (on ENST00000463781 / NM_018406.7; = p.L1126= on NM_004532.6) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV57762431, COSV57777555; called by muse, mutect2, varscan2
- MYH4 | c.2364C>T p.L788= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV55111246; called by muse, mutect2, varscan2
- MYT1L | c.2868G>T p.G956= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV67701031; called by muse, mutect2, varscan2
- NDST4 | c.1611C>G p.V537= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52107620; called by muse, mutect2, varscan2
- NOL9 | c.468C>T p.I156= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV60226579; called by muse, mutect2, varscan2
- OR10H1 | c.615C>T p.I205= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV58470576; called by muse, mutect2, varscan2
- OR12D3 | c.12C>T p.V4= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV65826201; called by muse, mutect2, varscan2
- OR2L13 | c.228C>A p.T76= | Silent (SNP) | VAF 62/271 reads (23%) | catalogued as COSV63547397; called by muse, mutect2, varscan2
- OR2W1 | c.276C>T p.I92= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs757179513, COSV65851348, COSV65852130; called by muse, mutect2, varscan2
- OR4K5 | c.858T>C p.I286= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV60002174, COSV60003400; called by muse, mutect2, varscan2
- OR4S2 | c.48T>C p.S16= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs1313450033, COSV56745460, COSV56747812; called by muse, mutect2, varscan2
- OSBPL7 | c.300G>T p.S100= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV50106404, COSV50111586; called by muse, mutect2, varscan2
- OSM | c.372G>A p.E124= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV53160612, COSV99304125; called by muse, mutect2
- OTUD7B | c.249C>G p.L83= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as COSV64914866; called by muse, mutect2, varscan2
- PAX9 | c.379C>T p.L127= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV64061635; called by muse, mutect2, varscan2
- PBXIP1 | c.1455G>A p.R485= | Silent (SNP) | VAF 24/406 reads (6%) | catalogued as COSV63776725; called by muse, mutect2
- PDIA6 | c.391C>T p.L131= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55348983; called by muse, mutect2, varscan2
- PGBD1 | c.150C>T p.F50= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52551138; called by muse, mutect2
- PLOD3 | c.207G>C p.L69= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV56181097; called by muse, mutect2, varscan2
- PPP4R3B | c.24G>A p.V8= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs1360485620, COSV55401152, COSV99702235; called by muse, mutect2, varscan2
- PRKAB2 | c.618C>T p.P206= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV54212492; called by muse, mutect2, varscan2
- PSD2 | c.1527C>G p.L509= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV51196987; called by muse, mutect2, varscan2
- PSKH2 | c.472C>A p.R158= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs377117660, COSV104372375, COSV52608961; called by muse, mutect2, varscan2
- PSTPIP1 | c.219G>A p.L73= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV51198048; called by muse, mutect2, varscan2
- RAB25 | c.510G>A p.L170= | Silent (SNP) | VAF 74/274 reads (27%) | catalogued as COSV63107458, COSV63107521, COSV63107764; called by muse, mutect2, varscan2
- RASGRF1 | c.2634C>G p.L878= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV67249159; called by muse, mutect2, varscan2
- RCOR3 | c.975G>A p.K325= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV65364334; called by muse, varscan2
- RHPN2 | c.1356C>T p.L452= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV54274262, COSV99577611; called by muse, mutect2, varscan2
- RIN2 | c.1233G>A p.K411= (on ENST00000255006 / NM_001242581.1; = p.K362= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1463830150, COSV54783691; called by muse, mutect2, varscan2
- SALL1 | c.1188C>T p.A396= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV51752583; called by muse, mutect2, varscan2
- SCN8A | c.4023C>T p.F1341= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV61975927; called by muse, mutect2, varscan2
- SDHA | c.1266G>C p.L422= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV53765103; called by muse, mutect2, varscan2
- SLC25A11 | c.231G>C p.L77= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV52590212; called by muse, varscan2
- SLC35D1 | c.261C>G p.L87= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV52429447; called by muse, mutect2, varscan2
- SLCO1B1 | c.450C>T p.L150= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV57006458; called by muse, varscan2
- SLCO1B3 | c.315A>C p.G105= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV53931308; called by muse, mutect2, varscan2
- SRRM2 | c.3171G>C p.L1057= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as rs754844000, COSV57067133; called by muse, mutect2, varscan2
- STAM | c.1254G>A p.G418= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs1554829686, COSV101098036; called by muse, mutect2, varscan2
- SZT2 | c.7221G>A p.R2407= (on ENST00000634258 / NM_001365999.1; = p.R2350= on NM_015284.4) | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV65166984; called by muse, mutect2
- TCAF1 | c.522C>T p.L174= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs780254168, COSV63517616; called by muse, mutect2, varscan2
- TGM2 | c.1839C>T p.L613= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs138893457, COSV63930955; called by muse, mutect2, varscan2
- TMEM174 | c.147G>C p.L49= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as COSV57113102; called by muse, mutect2
- TPP2 | c.39C>T p.H13= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1312399088, COSV65750674; called by muse, mutect2, varscan2
- TRIM6 | c.822G>C p.L274= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs753298201, COSV53474348; called by muse, mutect2, varscan2
- TSHZ3 | c.3021C>T p.S1007= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV53663127; called by muse, mutect2, varscan2
- TTC3 | c.2668C>T p.L890= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV61285145; called by muse, mutect2, varscan2
- TTN | c.97971C>T p.I32657= (on ENST00000591111; = p.I25233= on NM_003319.4) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV59861902; called by muse, mutect2, varscan2
- TUBA3E | c.132C>T p.G44= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs199812665, COSV57269381; called by muse, mutect2, varscan2
- TUBG1 | c.1355G>A p.*452= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV52220364; called by muse, mutect2, varscan2
- TUBGCP2 | c.114G>T p.P38= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV53302506; called by muse, mutect2, varscan2
- UGGT2 | c.2514G>A p.K838= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV65071886; called by muse, mutect2, varscan2
- UPF1 | c.1827G>A p.L609= (on ENST00000599848 / NM_001297549.2; = p.L598= on NM_002911.4) | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV53193386; called by muse, varscan2
- VWA7 | c.1245C>T p.F415= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV65172275; called by muse, mutect2, varscan2
- WSCD1 | c.1089G>A p.G363= | Silent (SNP) | VAF 74/138 reads (54%) | catalogued as COSV58493295; called by muse, mutect2, varscan2
- ZNF638 | c.1527A>T p.R509= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV52481419; called by muse, mutect2, varscan2
- AC244258.1 | n.978T>C | RNA (SNP) | VAF 72/164 reads (44%) | catalogued as rs778107389; called by muse, mutect2, varscan2
- AL645922.1 | c.256+729G>A | Intron (SNP) | VAF 15/63 reads (24%) | catalogued as COSV54959007; called by muse, mutect2, varscan2
- ATP11AUN | n.792C>T | RNA (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- BRWD1 | c.6571+148G>C | Intron (SNP) | VAF 16/159 reads (10%) | catalogued as COSV100313132; called by muse, mutect2, varscan2
- CALCA | chr11:14967718 G>T | 3'Flank (SNP) | VAF 6/62 reads (10%) | catalogued as COSV59027365; called by muse, mutect2
- DNMT3A | c.640-1453G>A | Intron (SNP) | VAF 28/101 reads (28%) | catalogued as COSV99261230; called by muse, mutect2, varscan2
- ESRRB | c.1296+404G>T | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as rs1437098477, COSV99835067; called by muse, mutect2, varscan2
- LIM2 | c.175+62C>A | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99702292; called by muse, varscan2
- LIM2 | c.175+61C>A | Intron (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99702294; called by muse, varscan2
- MDM4 | c.412-272G>A | Intron (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- MIR518A2 | n.30C>A | RNA (SNP) | VAF 51/161 reads (32%) | called by muse, mutect2, varscan2
- SGSM2 | c.1288+2042C>T | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99279959; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12696G>A | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as rs202142283; called by muse, mutect2, varscan2
- SNORD64 | n.9G>A | RNA (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16439356 G>A | 3'Flank (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- TSPAN14 | chr10:80520610 C>G | 3'Flank (SNP) | VAF 47/545 reads (9%) | catalogued as COSV99627810; called by muse, mutect2
- TTLL11 | c.1539+60C>T | Intron (SNP) | VAF 23/105 reads (22%) | catalogued as COSV58641550, COSV58644546; called by muse, mutect2, varscan2
- TTN | c.10360+1781G>A | Intron (SNP) | VAF 9/75 reads (12%) | catalogued as COSV59862014; called by muse, mutect2, varscan2
- VPS13D | c.13035+263G>A | Intron (SNP) | VAF 10/119 reads (8%) | catalogued as COSV99165980; called by muse, mutect2, varscan2
- XIRP2 | c.*529del | 3'UTR (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- ZNFX1 | chr20:49278960 C>T | 5'Flank (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
